Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A15Z, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A15Z-01A (Primary Tumor).

[page 1 of 2]
1CB-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Surgical Pathology

Site Code. Endometrium
C54.1

TISSUE DESCRIPTION:

B1 B2 B3 B4 B5 B6 B7 B8 C1 C2 C3 C4 C5 C6 D1 D2
D3 E1 E2

E3 E4 E5 E6 E7 E8 F1 F2 F3 F4

Uterus, right ovary (3.0 x 1.6 x 1.0 cm) with 6.0 cm
segment of
right fallopian tube, and left ovary (2.6 x 2.0 x 0.4 cm)
with 8.0

cm segment of left fallopian tube together weighing 145.0
grams;

right and left pelvic lymph nodes; right and left para-
aortic lymph

nodes; and tissue from the abdomen (skin and subcutaneous
tissue

with umbilicus, 3970.0 grams).

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes; total
hysterectomy

and bilateral salpingo-oophorectomy: FIGO grade II (of
III)

endometrial adenocarcinoma, endometrioid type, is
identified forming

a mass (4.2 x 3.6 x 1.1 cm) located in the right anterior
uterine

cavity. The tumor invades 0.6 cm into the myometrium
(total

myometrial thickness, 1.9 cm). The cervix and lower
uterine segment

are uninvolved by tumor.

Ovary, left, oophorectomy: Endosalpingiosis.

Ovary, right, oophorectomy: Unremarkable.

Fallopian tubes, left and right, salpingectomy:
Unremarkable.

Lymph nodes, right pelvic, excision: Multiple right
pelvic lymph

nodes (6 external iliac, 1 internal iliac, 4 common iliac,
1

obturator) are negative for tumor.

[page 2 of 2]
Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (4 external iliac, 2 internal iliac, 4 common iliac, 6 obturator) are negative for tumor.

Lymph nodes, left and right para-aortic, excision: A single right para-aortic lymph node below the inferior mesenteric artery is negative for tumor. Multiple (4) left para-aortic lymph nodes above the inferior mesenteric artery are negative for tumor.

Skin and subcutaneous tissue, abdomen, excision: Skin and subcutaneous tissue (3970.0 grams) with umbilicus identified grossly.

Source: NCI Genomic Data Commons file 9ea9748b-1163-429d-bfe4-31d479bdd095 (TCGA-D1-A15Z.280F86BF-4834-4FA9-B153-DE7BE312E619.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).